Somatic mutation profile of tumor specimen TCGA-DD-AAD6-01A (aliquot TCGA-DD-AAD6-01A-11D-A40R-10) from TCGA case TCGA-DD-AAD6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.2 years (24,185 days).
Specimen TCGA-DD-AAD6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 723858af-ce56-4890-b62f-d393cc637e43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAD6-10A (Blood Derived Normal), aliquot TCGA-DD-AAD6-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28fa8253-e30d-4783-83db-303726d1f30e

The open-access MAF lists 117 somatic variants for this specimen: 85 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 29, Frame Shift Del 4, Splice Site 4, Nonsense Mutation 2, 5'UTR 1, 5'Flank 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 38/94 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs771227157, COSV99771437; called by muse, mutect2, varscan2
- ABCA9 | c.2901+1G>C p.X967_splice | Splice Site (SNP) | VAF 17/122 reads (14%) | catalogued as COSV100383092; called by muse, mutect2, varscan2
- ABCG5 | c.1723C>G p.L575V | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs746277612, COSV99571179; called by muse, mutect2, varscan2
- ADAMTS20 | c.1104A>C p.K368N | Missense Mutation (SNP) | VAF 192/433 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV101239280; called by muse, mutect2, varscan2
- ADARB2 | c.597C>A p.H199Q | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV101186897, COSV101187053; called by muse, mutect2, varscan2
- ADGRF1 | c.2509T>C p.F837L | Missense Mutation (SNP) | VAF 146/325 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99347253; called by muse, mutect2, varscan2
- ALB | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs537985931, COSV99891436; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARMCX2 | c.1446C>A p.N482K | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100168148; called by muse, mutect2, varscan2
- ATAD2 | c.4087A>G p.I1363V | Missense Mutation (SNP) | VAF 253/314 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV99784670; called by muse, mutect2, varscan2
- ATP2C2 | c.99+1G>A p.X33_splice | Splice Site (SNP) | VAF 106/240 reads (44%) | catalogued as COSV99298032; called by muse, mutect2, varscan2
- BEND4 | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV101549742; called by muse, mutect2, varscan2
- BRIX1 | c.472T>C p.C158R | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100384552; called by muse, mutect2, varscan2
- CACNA1E | c.1573C>A p.L525M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV100702538; called by muse, mutect2, varscan2
- CCDC144A | c.4256T>C p.L1419P | Missense Mutation (SNP) | VAF 94/123 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100852790; called by muse, mutect2, varscan2
- CELF5 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs755859611, COSV99485944; called by muse, mutect2, varscan2
- CEP290 | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1017259177, COSV100468689; called by muse, mutect2, varscan2
- CEP44 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1488687493, COSV99639472; called by muse, mutect2, varscan2
- CNOT11 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99179285, COSV99179340; called by muse, mutect2, varscan2
- CNOT2 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99972624; called by muse, mutect2, varscan2
- COL3A1 | c.4073G>A p.R1358Q | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs745656610, COSV58596403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CT55 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 82/93 reads (88%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99358867; called by muse, mutect2, varscan2
- CTNNA3 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV57721691; called by muse, mutect2, varscan2
- CTNNBL1 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV100799520; called by muse, mutect2, varscan2
- CUBN | c.2460A>C p.E820D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.137); catalogued as COSV100912640; called by muse, mutect2, varscan2
- CYP2C8 | c.1433C>G p.S478C | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as COSV100987938; called by muse, mutect2, varscan2
- DST | c.3676A>G p.R1226G (on ENST00000361203 / NM_001374722.1; = p.R900G on NM_001723.6) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV99755622; called by muse, mutect2, varscan2
- DYNC1H1 | c.2537A>G p.K846R | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV100794856; called by muse, mutect2, varscan2
- FAM135B | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99357124; called by muse, mutect2, varscan2
- FASN | c.5444A>C p.Q1815P | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as COSV100147765; called by muse, mutect2, varscan2
- FBXO38 | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs571472179, COSV99693416; called by muse, varscan2
- FRYL | c.7790T>G p.I2597S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV99976859; called by muse, mutect2, varscan2
- GAB1 | c.1687A>T p.R563W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99528302; called by muse, mutect2, varscan2
- GRM2 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99622809; called by muse, mutect2, varscan2
- HIP1 | c.2710A>T p.M904L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100417498; called by muse, mutect2, varscan2
- HMGCS2 | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as COSV101024786, COSV65568632; called by muse, mutect2, varscan2
- HSPD1 | c.1024T>G p.L342V | Missense Mutation (SNP) | VAF 165/396 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100798375; called by muse, mutect2, varscan2
- IGSF5 | c.1008T>A p.N336K | Missense Mutation (SNP) | VAF 155/209 reads (74%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as COSV101012059; called by muse, mutect2, varscan2
- ITPKB | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as rs1386746066, COSV99684315; called by muse, mutect2, varscan2
- JAK3 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs1465717926, COSV101512928; called by muse, mutect2, varscan2
- KCNJ12 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs782577366, COSV100054796, COSV104404849; called by muse, mutect2, varscan2
- KIF11 | c.915A>T p.R305S | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV99585844; called by muse, mutect2, varscan2
- KIF1B | c.4004C>T p.S1335F (on ENST00000377086 / NM_001365952.1; = p.S1289F on NM_015074.3) | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99823247; called by muse, mutect2, varscan2
- KRT72 | c.1387T>C p.F463L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.023); catalogued as COSV99537247; called by muse, mutect2, varscan2
- KRT9 | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV99879188; called by muse, mutect2, varscan2
- MASP2 | c.1926T>G p.S642R | Missense Mutation (SNP) | VAF 90/100 reads (90%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV99534199; called by muse, mutect2, varscan2
- MEGF8 | c.2456A>G p.E819G (on ENST00000251268 / NM_001271938.2; = p.E752G on NM_001410.3) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99236140; called by muse, mutect2
- MUC16 | c.50T>A p.L17* | Nonsense Mutation (SNP) | VAF 64/84 reads (76%) | catalogued as COSV101199877; called by muse, mutect2, varscan2
- MYH11 | c.5908G>T p.A1970S | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV100258902; called by muse, mutect2, varscan2
- MYH7B | c.3748G>T p.E1250* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99328331; called by muse, mutect2, varscan2
- OTUB1 | c.802A>G p.I268V | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV99735145; called by muse, mutect2, varscan2
- PEBP1 | c.325T>A p.S109T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV99731943; called by muse, mutect2, varscan2
- PFKFB3 | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 96/227 reads (42%) | PolyPhen benign (0.025); catalogued as COSV100432021; called by muse, mutect2, varscan2
- POLR2M | c.201A>C p.E67D | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100221222; called by muse, mutect2
- PTK2 | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 144/206 reads (70%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); catalogued as COSV100570152; called by muse, mutect2, varscan2
- RAVER2 | c.511T>A p.C171S | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV99605143; called by muse, mutect2, varscan2
- RESF1 | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV100440328; called by muse, mutect2, varscan2
- RGS7 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as rs758148829, COSV58536063, COSV58564834; called by muse, mutect2, varscan2
- RNF123 | c.1136A>T p.K379M | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100570675; called by muse, mutect2, varscan2
- SDK2 | c.2246T>C p.V749A | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV101167592; called by muse, mutect2, varscan2
- SETD9 | c.827T>G p.V276G | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99605623; called by muse, mutect2, varscan2
- SLC25A10 | c.302A>T p.E101V | Missense Mutation (SNP) | VAF 98/144 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100519020; called by muse, varscan2
- SLC26A4 | c.2188C>G p.Q730E | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99706944; called by muse, mutect2, varscan2
- SP8 | c.1447C>G p.P483A (on ENST00000361443 / NM_198956.4; = p.P501A on NM_182700.6) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100815336; called by muse, mutect2, varscan2
- SYCP2 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs761447870, COSV100698246, COSV62765655; called by muse, mutect2, varscan2
- TAS2R13 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1265929978, COSV101183736; called by muse, mutect2, varscan2
- THOC1 | c.1143A>G p.I381M | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); catalogued as COSV99863401; called by muse, mutect2, varscan2
- TMEM132E | c.868C>A p.P290T (on ENST00000321639; = p.P380T on NM_001304438.2) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100396270; called by muse, mutect2, varscan2
- TNS3 | c.3691A>G p.N1231D | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100235511; called by muse, mutect2, varscan2
- UBAP2 | c.3202T>A p.L1068M | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as COSV99602195; called by muse, mutect2, varscan2
- UTRN | c.2925G>T p.E975D | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV100839897; called by muse, mutect2, varscan2
- UTRN | c.3823-1G>T p.X1275_splice | Splice Site (SNP) | VAF 32/70 reads (46%) | catalogued as COSV100839899; called by muse, mutect2, varscan2
- VRK2 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV99287549; called by muse, mutect2, varscan2
- WDR91 | c.1735A>G p.T579A | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100615691; called by muse, mutect2, varscan2
- ZNF281 | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54166507, COSV54167028; called by muse, mutect2, varscan2
- ZNF304 | c.1334G>T p.R445I | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99988623; called by muse, mutect2, varscan2
- ZNF415 | c.941G>T p.C314F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99701568; called by muse, mutect2, varscan2
- ZNF615 | c.1880A>G p.N627S | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100943795; called by muse, mutect2, varscan2
- ZNF785 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67876450; called by muse, mutect2, varscan2
- ALB | c.662_663del p.R221Tfs*30 | Frame Shift Del (DEL) | VAF 112/349 reads (32%) | called by pindel, varscan2
- CRMP1 | c.1521del p.A508Lfs*39 | Frame Shift Del (DEL) | VAF 61/175 reads (35%) | called by mutect2, pindel, varscan2
- NDUFS6 | c.143del p.D48Vfs*10 | Frame Shift Del (DEL) | VAF 49/137 reads (36%) | called by mutect2, pindel, varscan2
- PCNX1 | c.1179dup p.N394* | Frame Shift Ins (INS) | VAF 67/91 reads (74%) | called by mutect2, varscan2
- SLC4A2 | c.218-5_235del p.X73_splice | Splice Site (DEL) | VAF 34/104 reads (33%) | called by mutect2, varscan2
- USP34 | c.3662del p.P1221Lfs*4 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- AARS2 | c.990A>T p.T330= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV55116313, COSV99771436; called by muse, mutect2, varscan2
- ARHGEF10L | c.2280G>A p.E760= | Silent (SNP) | VAF 52/64 reads (81%) | catalogued as rs202159383; called by muse, mutect2, varscan2
- C3 | c.4977T>C p.F1659= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as COSV99836616; called by muse, mutect2, varscan2
- CAD | c.4569A>T p.A1523= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV99255004; called by muse, mutect2, varscan2
- COX15 | c.61C>T p.L21= | Silent (SNP) | VAF 91/172 reads (53%) | catalogued as rs1425549542, COSV99187076; called by muse, mutect2, varscan2
- CPZ | c.54C>A p.A18= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV100248968; called by muse, mutect2
- CUBN | c.3525G>T p.T1175= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as COSV100912639; called by muse, mutect2, varscan2
- DHX38 | c.2913C>A p.I971= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV99194307; called by muse, mutect2, varscan2
- DIAPH1 | c.879A>G p.E293= | Silent (SNP) | VAF 72/159 reads (45%) | catalogued as COSV99526531; called by muse, mutect2, varscan2
- DSCAML1 | c.495G>A p.A165= (on ENST00000321322; = p.A105= on NM_020693.4) | Silent (SNP) | VAF 45/64 reads (70%) | catalogued as rs1169936530, COSV100355932; called by muse, mutect2, varscan2
- FLT4 | c.3408C>T p.A1136= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV99986988; called by muse, mutect2, varscan2
- FOXA2 | c.1077G>T p.P359= (on ENST00000377115 / NM_153675.3; = p.P365= on NM_021784.5) | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs1189848148, COSV101008352; called by muse, mutect2, varscan2
- FSTL5 | c.2241C>G p.S747= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as rs1292640381, COSV100055336; called by muse, mutect2, varscan2
- FXR1 | c.318A>T p.I106= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV99976367; called by muse, mutect2
- KMT2D | c.8281C>T p.L2761= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV56427994; called by muse, mutect2, varscan2
- LIMK1 | c.981C>G p.V327= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV100283167; called by muse, mutect2, varscan2
- MROH1 | c.3327G>A p.E1109= | Silent (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- MYLK | c.1647G>T p.L549= | Silent (SNP) | VAF 198/432 reads (46%) | catalogued as COSV100659046; called by muse, mutect2, varscan2
- NOSIP | c.480C>T p.P160= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV100182235; called by muse, mutect2, varscan2
- NRBP2 | c.1308G>A p.A436= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as rs143477290; called by muse, mutect2, varscan2
- PAPPA2 | c.1065C>T p.S355= | Silent (SNP) | VAF 53/109 reads (49%) | catalogued as COSV100866781, COSV62784930; called by muse, mutect2, varscan2
- PLSCR4 | c.951C>T p.F317= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs771711885, COSV100724204; called by muse, mutect2, varscan2
- POLQ | c.5097T>C p.N1699= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV99952226; called by muse, mutect2, varscan2
- PSMC6 | c.723A>G p.P241= (on ENST00000612399; = p.P227= on NM_002806.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as COSV101471201; called by muse, mutect2, varscan2
- TBC1D9 | c.2691A>G p.L897= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV101464339; called by muse, mutect2, varscan2
- TM9SF4 | c.535C>T p.L179= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as COSV99454504; called by muse, mutect2, varscan2
- TRMT1L | c.672A>T p.P224= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV100834619; called by muse, mutect2, varscan2
- TTN | c.52974T>C p.N17658= (on ENST00000591111; = p.N10234= on NM_003319.4) | Silent (SNP) | VAF 70/135 reads (52%) | catalogued as COSV100611825; called by muse, mutect2, varscan2
- ZNF335 | c.1191A>T p.P397= | Silent (SNP) | VAF 54/97 reads (56%) | catalogued as COSV100532984; called by muse, mutect2, varscan2
- ADAD2 | c.419-407G>A | Intron (SNP) | VAF 77/160 reads (48%) | catalogued as rs1158518611, COSV99235307; called by muse, mutect2, varscan2
- NIM1K | c.-1G>T | 5'UTR (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100390135; called by muse, mutect2, varscan2
- POLR3D | chr8:22244995 T>C | 5'Flank (SNP) | VAF 20/61 reads (33%) | catalogued as rs1029283088; called by muse, mutect2, varscan2
